Somatic mutation profile of tumor specimen 0DI6L0 from CCDI case PBBVEH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 13.3 years (4,850 days).
Specimen 0DI6L0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37d65b78-ab49-46e8-9403-bbf6a8cc7d97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI6KG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39a5ea28-bae9-4cd5-8e58-b3453d27c3cf

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Intron 1, 3'UTR 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASTN2 | c.3692C>T p.S1231L (on ENST00000313400 / NM_001365069.1; = p.S1180L on NM_014010.5) | Missense Mutation (SNP) | VAF 338/850 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs1458214989, COSV55999388; called by muse, mutect2, varscan2
- KBTBD7 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 353/807 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.498); catalogued as rs1299660947, COSV101068088; called by muse, mutect2, varscan2
- BYSL | c.12C>G p.F4L | Missense Mutation (SNP) | VAF 250/531 reads (47%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCDC1 | c.4109A>C p.D1370A (on ENST00000597505 / NM_001367979.1; = p.D477A on NM_020869.3) | Missense Mutation (SNP) | VAF 168/334 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNMBP | c.2477G>A p.G826E | Missense Mutation (SNP) | VAF 362/774 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MBOAT7 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 235/504 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.076); called by mutect2, varscan2
- MRI1 | c.163_171del p.G55_L57del | In Frame Del (DEL) | VAF 191/211 reads (91%) | called by mutect2, pindel, varscan2
- MTIF3 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 26/1040 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2
- MTR | c.1777G>T p.A593S | Missense Mutation (SNP) | VAF 308/655 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- PIWIL3 | c.1181C>A p.P394H | Missense Mutation (SNP) | VAF 554/1150 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PPARGC1B | c.2237G>A p.G746D | Missense Mutation (SNP) | VAF 256/578 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- TTC30B | c.115C>G p.Q39E | Missense Mutation (SNP) | VAF 24/602 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2
- MGAT4D | c.366A>T p.V122= | Silent (SNP) | VAF 252/564 reads (45%) | called by muse, mutect2, varscan2
- SARDH | c.1233C>T p.S411= | Silent (SNP) | VAF 259/575 reads (45%) | catalogued as rs765083603; called by muse, mutect2, varscan2
- PPT2 | chr6:32153616 C>G | 5'Flank (SNP) | VAF 204/484 reads (42%) | called by muse, mutect2, varscan2
- RNF220 | c.1629+20G>A | Intron (SNP) | VAF 48/1124 reads (4%) | catalogued as rs548447621; called by muse, mutect2
- RPL26L1 | c.*22C>T | 3'UTR (SNP) | VAF 136/710 reads (19%) | catalogued as rs541290184, COSV99442616; called by muse, mutect2, varscan2
